PECGS case C083-000074 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/258aad55-ed0d-42d9-b50a-1bdf93ad0105

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 37 years; Year of birth: 1979; Education level: High School Graduate or GED.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectosigmoid junction; Age at diagnosis: 36.9 years (13,478 days); AJCC clinical stage: Stage IIIA; AJCC pathologic stage: Stage IIIB; Progression or recurrence: yes; Days to last follow up: 2,600 days (7.1 years).
2. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 36.9 years (13,478 days); AJCC clinical stage: Stage IIA; AJCC pathologic stage: Stage IIIB; Progression or recurrence: yes; Days to last follow up: 2,600 days (7.1 years).

Biospecimens (2 samples)
- Sample C083-000074_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000074_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
